Somatic mutation profile of tumor specimen TCGA-29-1771-01A (aliquot TCGA-29-1771-01A-01W-0633-09) from TCGA case TCGA-29-1771, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G2; Age at diagnosis: 76.9 years (28,093 days).
Specimen TCGA-29-1771-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e500eca8-e46d-491f-9953-70806eee929f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-29-1771-10A (Blood Derived Normal), aliquot TCGA-29-1771-10A-01W-0634-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ce40b8e5-0b05-412e-8b44-9b8d134d4774

The open-access MAF lists 25 somatic variants for this specimen: 21 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 18, Silent 4, Frame Shift Del 2, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MYO7A | c.722G>A p.R241H | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs111033284, CM071027, CM1110176, COSV68683548; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.530C>G p.P177R | Missense Mutation (SNP) | VAF 9/90 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.731); catalogued as rs751477326, CM102507, COSV52661381, COSV52721872, COSV52783879; ClinVar: uncertain significance / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ADCY2 | c.592T>A p.F198I | Missense Mutation (SNP) | VAF 72/191 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV57859849; called by muse, mutect2, varscan2
- BIK | c.46C>T p.L16F | Missense Mutation (SNP) | VAF 20/118 reads (17%) | SIFT tolerated (0.91); PolyPhen benign (0.026); catalogued as COSV53336952; called by muse, mutect2, varscan2
- FBXW4 | c.1462G>A p.E488K | Missense Mutation (SNP) | VAF 17/35 reads (49%) | SIFT deleterious (0.01); PolyPhen benign (0.34); catalogued as COSV58706755; called by muse, mutect2, varscan2
- FRMPD4 | c.42-2A>T p.X14_splice | Splice Site (SNP) | VAF 10/74 reads (14%) | catalogued as COSV66225943; called by mutect2, varscan2
- GRIN2B | c.559C>T p.R187C | Missense Mutation (SNP) | VAF 19/520 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV74206768; called by muse, mutect2
- H2BC13 | c.128del p.Y43Sfs*4 | Frame Shift Del (DEL) | VAF 31/212 reads (15%) | catalogued as COSV62440462, COSV62441065; called by mutect2, varscan2
- IGSF3 | c.2935C>T p.R979C (on ENST00000369486 / NM_001007237.3; = p.R999C on NM_001542.4) | Missense Mutation (SNP) | VAF 25/51 reads (49%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.791); catalogued as rs1279277775, CD1411593, COSV59586547; called by muse, mutect2, varscan2
- KAT6B | c.5059G>C p.D1687H | Missense Mutation (SNP) | VAF 10/244 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99767452; called by muse, mutect2
- KMT2A | c.9959G>A p.S3320N | Missense Mutation (SNP) | VAF 161/347 reads (46%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as COSV63282341; called by muse, mutect2, varscan2
- MON1B | c.1100G>A p.R367Q | Missense Mutation (SNP) | VAF 29/81 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.489); catalogued as COSV50245419; called by muse, mutect2, varscan2
- NF1 | c.4333_4337del p.I1445Sfs*20 (on ENST00000358273 / NM_001042492.3; = p.I1424Sfs*20 on NM_000267.3) | Frame Shift Del (DEL) | VAF 7/8 reads (88%) | catalogued as COSV62193787; called by mutect2, varscan2
- RACK1 | c.304G>C p.V102L | Missense Mutation (SNP) | VAF 8/106 reads (8%) | SIFT tolerated (0.22); PolyPhen benign (0.055); catalogued as COSV100958655; called by muse, mutect2
- RAPH1 | c.3353A>C p.K1118T | Missense Mutation (SNP) | VAF 40/54 reads (74%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.722); catalogued as COSV99863456; called by muse, mutect2, varscan2
- RAPH1 | c.3352A>G p.K1118E | Missense Mutation (SNP) | VAF 39/54 reads (72%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.368); catalogued as COSV99863458; called by muse, mutect2, varscan2
- SALL1 | c.2911G>A p.D971N | Missense Mutation (SNP) | VAF 19/58 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV51753548; called by muse, mutect2, varscan2
- SLC25A12 | c.1209G>C p.K403N | Missense Mutation (SNP) | VAF 10/246 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV99784741; called by muse, mutect2
- TBC1D4 | c.2519G>A p.R840K | Missense Mutation (SNP) | VAF 8/84 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as COSV100884539; called by muse, mutect2, varscan2
- UTP14C | c.796G>A p.E266K | Missense Mutation (SNP) | VAF 7/244 reads (3%) | SIFT deleterious (0.03); PolyPhen benign (0.055); catalogued as COSV101584253; called by muse, mutect2
- SPIN2B | c.167A>T p.H56L | Missense Mutation (SNP) | VAF 32/566 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.821); called by muse, mutect2
- HERC1 | c.8025G>T p.V2675= | Silent (SNP) | VAF 4/21 reads (19%) | catalogued as COSV71246014; called by muse, mutect2
- KCTD12 | c.855C>T p.S285= | Silent (SNP) | VAF 3/8 reads (38%) | catalogued as rs1488381206, COSV58524894; called by muse, mutect2
- KMT2B | c.4293C>G p.L1431= | Silent (SNP) | VAF 10/14 reads (71%) | catalogued as rs753088021, COSV55857400; called by muse, mutect2, varscan2
- ZFHX4 | c.4272G>A p.A1424= | Silent (SNP) | VAF 110/243 reads (45%) | catalogued as rs199795783; called by muse, mutect2, varscan2
